Somatic mutation profile of tumor specimen TCGA-02-2483-01A (aliquot TCGA-02-2483-01A-01D-1494-08) from TCGA case TCGA-02-2483, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 43.7 years (15,964 days).
Specimen TCGA-02-2483-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9d5be77-a14a-45ac-ac76-ac7e74e07c0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-02-2483-10A (Blood Derived Normal), aliquot TCGA-02-2483-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7682e0ce-e404-4c3e-acd2-126d5c7f57e9

The open-access MAF lists 50 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 10, Splice Site 1, 3'UTR 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 44/118 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 52/58 reads (90%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.2143G>A p.V715M | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs552175669, COSV54386405, COSV54400473; called by muse, mutect2, varscan2
- ANKRD26 | c.1459A>G p.M487V | Missense Mutation (SNP) | VAF 123/319 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as rs1441201952, COSV65793172; called by muse, mutect2, varscan2
- ATP11A | c.2369G>A p.S790N | Missense Mutation (SNP) | VAF 95/197 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52107006; called by muse, mutect2, varscan2
- ATRX | c.6003del p.W2001Cfs*14 | Frame Shift Del (DEL) | VAF 58/100 reads (58%) | catalogued as CS081873; called by mutect2, pindel, varscan2
- BICC1 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.1); catalogued as COSV54063956; called by muse, mutect2, varscan2
- C1orf141 | c.386T>C p.V129A | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV63992255; called by muse, mutect2, varscan2
- C3 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.212); catalogued as rs758391076, COSV55573642; called by muse, mutect2
- CCDC146 | c.493A>T p.I165L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53544811; called by muse, mutect2, varscan2
- CHL1 | c.197+1G>A p.X66_splice | Splice Site (SNP) | VAF 25/55 reads (45%) | catalogued as COSV56587931; called by muse, mutect2, varscan2
- GAS2L1 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs764937314, COSV53330280; called by muse, mutect2
- GFRAL | c.752A>T p.K251M | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61231250; called by muse, mutect2
- GRAMD2A | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV59032834; called by muse, mutect2, varscan2
- GRIN3B | c.1370A>G p.D457G | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV52258920; called by muse, mutect2, varscan2
- HIPK2 | c.2690A>G p.E897G | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61227936; called by muse, mutect2, varscan2
- IGHMBP2 | c.2144G>A p.G715D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV54820475; called by muse, mutect2, varscan2
- IRAK3 | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV54159111; called by muse, mutect2
- KRT9 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.092); catalogued as COSV55851716; called by muse, mutect2, varscan2
- LRRC31 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555692167, COSV52979800; called by muse, mutect2, varscan2
- MPP7 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61730425; called by muse, mutect2, varscan2
- NXN | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as rs777902672, COSV61094452; called by muse, mutect2, varscan2
- OR5B12 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.034); catalogued as COSV56905166; called by muse, mutect2
- OR5L1 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV61732992; called by muse, mutect2, varscan2
- PARN | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV58366576; called by muse, mutect2
- PGLYRP4 | c.631C>G p.P211A | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV62835345; called by muse, mutect2
- PNMA8A | c.935G>T p.W312L | Missense Mutation (SNP) | VAF 132/430 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV58136051; called by muse, mutect2, varscan2
- PNMA8A | c.934T>A p.W312R | Missense Mutation (SNP) | VAF 133/423 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV58136070; called by muse, mutect2, varscan2
- PNPLA6 | c.4123G>A p.A1375T (on ENST00000414982 / NM_001166111.2; = p.A1327T on NM_006702.5) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV55374514; called by muse, mutect2, varscan2
- SBSN | c.1551C>A p.H517Q (on ENST00000452271 / NM_001166034.2; = p.H174Q on NM_198538.4) | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); catalogued as COSV71733261; called by muse, mutect2
- SEMA3C | c.1576C>G p.L526V | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54842266; called by muse, mutect2, varscan2
- SLCO5A1 | c.1649A>G p.N550S | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV52660010; called by muse, mutect2
- TAF2 | c.3512A>G p.H1171R | Missense Mutation (SNP) | VAF 592/874 reads (68%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.074); catalogued as COSV65416984; called by muse, mutect2, varscan2
- TNFSF11 | c.253C>A p.H85N | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99520739; called by muse, mutect2
- TOMM70 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52522434; called by muse, mutect2, varscan2
- TRPV6 | c.1655T>C p.F552S | Missense Mutation (SNP) | VAF 14/325 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63891927; called by muse, mutect2
- ZNF155 | c.807C>A p.F269L | Missense Mutation (SNP) | VAF 10/307 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54206953; called by muse, mutect2
- ZNF646 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as rs775176471, COSV56211940; called by muse, mutect2, varscan2
- AC008397.2 | c.633C>T p.D211= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs760869430, COSV53205187; called by muse, mutect2, varscan2
- BIN2 | c.1347G>A p.R449= | Silent (SNP) | VAF 42/130 reads (32%) | catalogued as COSV57203939; called by muse, mutect2, varscan2
- EP300 | c.4041A>G p.G1347= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as COSV54333355; called by muse, mutect2
- FBXO43 | c.1338A>C p.V446= | Silent (SNP) | VAF 18/582 reads (3%) | catalogued as COSV71054064; called by muse, mutect2
- KCTD8 | c.1236C>A p.L412= | Silent (SNP) | VAF 36/648 reads (6%) | catalogued as COSV63589565; called by muse, mutect2
- MPP7 | c.756T>C p.A252= | Silent (SNP) | VAF 36/169 reads (21%) | catalogued as COSV61730432; called by muse, mutect2, varscan2
- PHACTR4 | c.870G>A p.P290= (on ENST00000373839 / NM_001350159.2; = p.P300= on NM_023923.4) | Silent (SNP) | VAF 83/203 reads (41%) | catalogued as rs201982408; called by muse, mutect2, varscan2
- PLD1 | c.1137A>G p.T379= | Silent (SNP) | VAF 7/124 reads (6%) | catalogued as COSV60568348; called by muse, mutect2
- SPTBN1 | c.2799C>A p.L933= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV61686153; called by muse, mutect2, varscan2
- TAS2R9 | c.90T>A p.V30= | Silent (SNP) | VAF 114/251 reads (45%) | catalogued as COSV53688057; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3849G>T | 3'UTR (SNP) | VAF 97/322 reads (30%) | catalogued as COSV53972583; called by muse, mutect2
- SNORD116-12 | n.15T>C | RNA (SNP) | VAF 46/164 reads (28%) | called by muse, mutect2, varscan2
